Somatic mutation profile of tumor specimen TCGA-DX-A2IZ-01A (aliquot TCGA-DX-A2IZ-01A-11D-A21Q-09) from TCGA case TCGA-DX-A2IZ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.9 years (22,245 days).
Specimen TCGA-DX-A2IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05cd3db6-7a24-4dd9-af84-c781aa70e410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A2IZ-10A (Blood Derived Normal), aliquot TCGA-DX-A2IZ-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00e8051d-7a1b-42f5-a66c-3c3921819fc4

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 25, Silent 8, Frame Shift Del 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCT2 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 202/229 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV54740941; called by muse, mutect2, varscan2
- EFHD2 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1283627922; called by mutect2, varscan2
- LRP1 | c.4390G>T p.D1464Y | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54501419; called by muse, mutect2, varscan2
- RASGRF1 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs199661393; called by muse, mutect2, varscan2
- RGR | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs201335015, COSV100812996, COSV63893643; called by muse, mutect2, varscan2
- SPN | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs181483014, COSV64070418; called by muse, mutect2, varscan2
- TRAK2 | c.927A>C p.K309N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.112); catalogued as COSV60274046; called by muse, mutect2, varscan2
- AK7 | c.724del p.V242Ffs*8 | Frame Shift Del (DEL) | VAF 47/366 reads (13%) | called by mutect2, pindel, varscan2
- ARL13B | c.1157del p.P386Lfs*41 (on ENST00000394222 / NM_001174150.2; = p.P279Lfs*41 on NM_144996.4) | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- CEP290 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 188/199 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHN1 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CLVS1 | c.956_958del p.C319del | In Frame Del (DEL) | VAF 21/41 reads (51%) | called by mutect2, pindel, varscan2
- DCTN4 | c.995del p.P332Qfs*8 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- DPH6 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.7995T>G p.N2665K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FSTL4 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALNT5 | c.901T>G p.L301V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INA | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- L1TD1 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2
- MBD6 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 108/603 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MET | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRDC | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 316/356 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- PCLO | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- PTPRC | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- RSPH6A | c.1804A>G p.M602V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SHMT2 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TESPA1 | c.1550C>T p.A517V (on ENST00000316577 / NM_001098815.3; = p.A379V on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM236 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TRIM22 | c.1441T>C p.Y481H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK7 | c.477G>A p.A159= | Silent (SNP) | VAF 22/207 reads (11%) | catalogued as rs757608679; called by muse, mutect2, varscan2
- EPHB2 | c.612C>T p.G204= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs773852423, COSV101006720, COSV101006802; called by muse, mutect2, varscan2
- FER1L6 | c.4896C>A p.G1632= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- HNRNPDL | c.333C>T p.H111= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as rs758689857, COSV55022093; called by muse, mutect2, varscan2
- KRT6C | c.1443T>C p.V481= | Silent (SNP) | VAF 32/38 reads (84%) | called by muse, mutect2, varscan2
- REV3L | c.6990T>G p.S2330= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- SERPINB1 | c.108A>C p.S36= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- ZHX3 | c.423C>T p.N141= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs113667928; called by muse, mutect2, varscan2
